Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96L, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96L-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

Tumor: 6.0 x 6.0 x 4.5 cm

Infiltration of mediastinal fat tissue

Diagnosis:

Type B3-Thymoma

pT3, pN0 (0/1)

Masaoka: III

Immunohistochemistry

epithelial cells positive for: p63, CK5/6
strong membrane staining for EGFR

epithelial cells negative for: CD117, synaptophysin, chromogranin A
Ki-67: 30%

CD5-, CD99-positive immature T-lymphocytes

ICD-O 3

Thymoma, type B3
malignant 8585/3

Site Thymus C37.9
QW 4/7/14

Source: NCI Genomic Data Commons file 1b40e398-ea63-4001-b91f-0afe64be69a6 (TCGA-ZB-A96L.34552D21-69AE-4955-9BFB-57EA5DC127B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).